PECGS case C083-000071 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/ee2dda53-a4c5-450c-ac33-571e915c8ed5

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 63 years; Year of birth: 1958; Education level: Professional or Graduate Degree.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Age at diagnosis: 62.9 years (22,974 days); AJCC clinical stage: Stage I; AJCC pathologic stage: Stage I; Progression or recurrence: no.

Other clinical attributes
- BMI: 17.76; Menopause status: Postmenopausal.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 2; Alcohol history: No.

Biospecimens (2 samples)
- Sample C083-000071_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000071_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
